Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A957, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A957-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Uterine cervix biopsy:

- Infiltrative poorly differentiated squamous cell carcinoma.

ICD-O.3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS C539
QW 8/12/14

ICDPA Discrepancy		☒
Site: Malignancy History		☒

Source: NCI Genomic Data Commons file 50a6ae57-dc75-4f97-9df9-5cb9624d12ae (TCGA-VS-A957.A1599777-E100-4429-8872-764AE82C9258.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).